Somatic mutation profile of tumor specimen TCGA-P3-A5QF-01A (aliquot TCGA-P3-A5QF-01A-11D-A28R-08) from TCGA case TCGA-P3-A5QF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper Gum; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.4 years (18,035 days).
Specimen TCGA-P3-A5QF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 173b4c90-7cdd-4c58-af4e-50ba52070f9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A5QF-10A (Blood Derived Normal), aliquot TCGA-P3-A5QF-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adb2e7cb-caee-44b9-ae92-f43cb6d6e1a0

The open-access MAF lists 403 somatic variants for this specimen: 281 protein-altering or splice-affecting, 108 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 247, Silent 108, Nonsense Mutation 25, Intron 5, RNA 5, Frame Shift Del 4, Splice Site 3, 3'UTR 2, Nonstop Mutation 1, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1708C>T p.R570W (on ENST00000372530 / NM_001198934.2; = p.R527W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/158 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376706540, COSV55085131; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NSD1 | c.6014G>A p.R2005Q | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587784174, CM030080, COSV100729769; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 56/88 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- POLG | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as rs1567192879, CM078477, COSV99175042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.3142T>C p.W1048R | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52707698; called by muse, mutect2, varscan2
- ABCA3 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as rs988110580, CD138702, COSV57055676; called by muse, mutect2, varscan2
- ABCA9 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100383439; called by muse, mutect2, varscan2
- ABCC5 | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 117/189 reads (62%) | catalogued as COSV99656652; called by muse, mutect2, varscan2
- ABCC8 | c.1161G>C p.L387F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100217685; called by muse, mutect2, varscan2
- ABTB2 | c.2937G>A p.M979I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100132087; called by muse, mutect2, varscan2
- ABTB2 | c.2219G>C p.G740A | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV100132092; called by muse, mutect2, varscan2
- ACTR8 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs1030608705, COSV99213887; called by muse, mutect2, varscan2
- ADAM23 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 101/270 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV100008680, COSV52223107; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1863G>C p.E621D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as rs758641874, COSV99647881; called by muse, mutect2, varscan2
- AFF4 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 51/74 reads (69%) | catalogued as COSV99535354; called by muse, mutect2, varscan2
- AHNAK2 | c.2336A>G p.D779G | Missense Mutation (SNP) | VAF 120/363 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100318832; called by muse, mutect2, varscan2
- ANKRD26 | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV101063367; called by muse, mutect2
- APC2 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV99279823; called by muse, mutect2, varscan2
- APP | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100696230; called by muse, mutect2, varscan2
- ARHGEF4 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.661); catalogued as rs375298090, COSV100388627, COSV58119106; called by muse, mutect2, varscan2
- ASPM | c.6978G>A p.M2326I | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV54134698; called by muse, mutect2, varscan2
- ASXL2 | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55462552; called by muse, mutect2, varscan2
- ATP10D | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV99906143; called by muse, mutect2, varscan2
- ATP2C1 | c.2660C>T p.S887L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as CM032195, COSV100146970; called by muse, mutect2, varscan2
- BICD2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376208721; called by muse, mutect2, varscan2
- BOD1L1 | c.5812G>A p.E1938K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99240303; called by muse, mutect2, varscan2
- BOLA1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64966676; called by muse, mutect2, varscan2
- BPIFB4 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV64950990; called by muse, mutect2, varscan2
- BRWD1 | c.5159C>G p.S1720* | Nonsense Mutation (SNP) | VAF 38/94 reads (40%) | catalogued as COSV100314016; called by muse, mutect2, varscan2
- C1S | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 143/363 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100196775; called by muse, mutect2, varscan2
- C2CD3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV100487359; called by muse, mutect2, varscan2
- CACNA1F | c.3642G>C p.Q1214H | Missense Mutation (SNP) | VAF 51/70 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100545343; called by muse, mutect2, varscan2
- CACNA2D1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV100667186; called by muse, mutect2, varscan2
- CACNG8 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs750396252, COSV54415420, COSV99555140; called by muse, mutect2, varscan2
- CADPS2 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV100465670; called by muse, mutect2
- CCDC22 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 36/44 reads (82%) | catalogued as COSV100873255; called by muse, mutect2, varscan2
- CCDC85A | c.497A>T p.K166M | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339554; called by muse, mutect2, varscan2
- CELA3A | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV99266717; called by muse, mutect2, varscan2
- CELSR1 | c.7204G>A p.E2402K | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs1213473560, COSV99419881; called by muse, mutect2, varscan2
- CEMIP2 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100987504; called by muse, mutect2, varscan2
- CEP290 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.337); catalogued as rs1166981120, COSV99898654; called by muse, mutect2, varscan2
- CEP350 | c.7512G>C p.L2504F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100855156, COSV100855177; called by muse, mutect2, varscan2
- CEP350 | c.7954C>T p.H2652Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV100855178; called by muse, mutect2, varscan2
- CEP89 | c.2284C>G p.Q762E | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs762386606, COSV99993956; called by muse, mutect2, varscan2
- CERK | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 140/267 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53453435, COSV99348785; called by muse, mutect2, varscan2
- CGNL1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 179/494 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99849073; called by muse, mutect2, varscan2
- CHD9 | c.2267G>C p.R756T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.382); catalogued as rs371787563; called by muse, varscan2
- CINP | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV53736249, COSV99392235; called by muse, mutect2, varscan2
- CLCA4 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201791111, COSV55368265; called by muse, mutect2, varscan2
- CLDN12 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV99842216; called by muse, mutect2, varscan2
- CLDN16 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 245/399 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99290356; called by muse, mutect2, varscan2
- CLK2 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100751921; called by muse, varscan2
- CNIH2 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100268549; called by muse, mutect2, varscan2
- COL12A1 | c.7970C>G p.S2657* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100486415; called by muse, mutect2, varscan2
- COL4A3 | c.5006G>C p.R1669T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV101170530; called by muse, mutect2, varscan2
- CST3 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100976886; called by muse, mutect2, varscan2
- CST9L | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs756626927, COSV65408541; called by muse, mutect2
- CTNNA3 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV101051467; called by muse, mutect2
- DENND4A | c.3565G>A p.E1189K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV101475421; called by muse, mutect2, varscan2
- DHDDS | c.198G>C p.L66F | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99360649; called by muse, mutect2
- DNAH10 | c.13054C>T p.P4352S (on ENST00000409039; = p.P4291S on NM_207437.3) | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV99435877; called by muse, mutect2, varscan2
- DNAJB4 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs749076879, COSV100883492; called by muse, mutect2, varscan2
- DOCK5 | c.2149G>C p.E717Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99377766; called by muse, mutect2
- DSC1 | c.1437G>C p.Q479H | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV99938232; called by muse, mutect2, varscan2
- DSC3 | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV100844712; called by muse, mutect2, varscan2
- DSP | c.5455A>G p.I1819V | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV101131721; called by muse, mutect2, varscan2
- DST | c.20383G>C p.E6795Q (on ENST00000361203 / NM_001374722.1; = p.E4492Q on NM_015548.5) | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99759570; called by muse, mutect2, varscan2
- DST | c.11635G>C p.E3879Q (on ENST00000361203 / NM_001374722.1; = p.E1467Q on NM_015548.5) | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); catalogued as COSV55015889; called by muse, mutect2
- E2F3 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100686244; called by muse, mutect2, varscan2
- ECH1 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.776); catalogued as COSV55489707, COSV99669654, COSV99669699; called by muse, varscan2
- ECI2 | c.511G>A p.E171K (on ENST00000380118 / NM_206836.3; = p.E141K on NM_006117.2) | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as COSV60986370, COSV60988714; called by muse, mutect2, varscan2
- EHF | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV99141043; called by muse, mutect2, varscan2
- EID1 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100195271; called by muse, mutect2, varscan2
- EPHA2 | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV100626268; called by muse, mutect2
- EPHA2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1299045926, COSV100626269; called by muse, mutect2
- EPS8 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843635; called by muse, mutect2
- ERBB3 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 85/288 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1235897459, COSV57249648; called by muse, mutect2, varscan2
- ERCC6L2 | c.823C>G p.H275D | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99998970; called by muse, mutect2, varscan2
- EXO5 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.777); catalogued as COSV99591423; called by muse, mutect2
- FAM133A | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV100220641; called by muse, mutect2, varscan2
- FANCM | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV99951588; called by muse, mutect2
- FASTKD3 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1433282889, COSV99242073; called by muse, mutect2, varscan2
- FBXL2 | c.1130A>G p.Q377R | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as rs754048674, COSV99371518; called by muse, mutect2, varscan2
- FGD2 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99236597; called by muse, mutect2
- FMNL2 | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as COSV99980703; called by muse, mutect2, varscan2
- FRAS1 | c.3275C>G p.S1092C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.502); catalogued as COSV53608531; called by muse, mutect2, varscan2
- FRYL | c.4121C>A p.A1374E | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99977994; called by muse, mutect2, varscan2
- FZD6 | c.1791G>A p.M597I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100708488; called by muse, mutect2, varscan2
- GAD1 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100713921, COSV100713926; called by muse, mutect2, varscan2
- GLIS3 | c.1830G>C p.E610D | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs942467208, COSV100173490, COSV100174757; called by muse, mutect2
- GLIS3 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV100174758; called by muse, mutect2, varscan2
- GUCY1B1 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.048); catalogued as COSV100025872; called by muse, varscan2
- GUCY1B1 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.634); catalogued as COSV100025874, COSV52378307; called by muse, varscan2
- GYS1 | c.504G>C p.Q168H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV99621162; called by muse, mutect2, varscan2
- HELB | c.2072C>G p.S691* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV99922180; called by muse, mutect2, varscan2
- HELZ2 | c.2687G>A p.R896H (on ENST00000467148 / NM_001037335.2; = p.R327H on NM_033405.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756394934, COSV100915692; called by muse, varscan2
- HIPK1 | c.2827C>G p.P943A | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100479620, COSV61249647; called by muse, mutect2, varscan2
- HIVEP3 | c.4511C>G p.S1504* | Nonsense Mutation (SNP) | VAF 4/82 reads (5%) | catalogued as COSV56016975, COSV99913862; called by muse, mutect2
- HNRNPDL | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99787210; called by muse, mutect2, varscan2
- HPS5 | c.3336G>C p.L1112F (on ENST00000349215 / NM_181507.2; = p.L998F on NM_007216.4) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV100752361; called by muse, mutect2
- HRNR | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1408448417, COSV100913896; called by muse, mutect2
- HSPE1 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99291555; called by muse, mutect2
- IFNGR2 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV99062396, COSV99274868; called by muse, mutect2, varscan2
- IFRD2 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100269195; called by muse, mutect2, varscan2
- IGLV3-25 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs189679814; called by muse, mutect2, varscan2
- IL21R | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs758877703, COSV100560525; called by muse, mutect2, varscan2
- ISX | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.087); catalogued as COSV100434181; called by muse, varscan2
- ITPR3 | c.3940G>C p.V1314L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as COSV100968070; called by muse, mutect2, varscan2
- JAK2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs757898652, COSV67596272, COSV67632399; called by muse, mutect2, varscan2
- JAKMIP2 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as rs777020968, COSV99509186; called by muse, mutect2, varscan2
- KCND2 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 134/401 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs529186706, COSV100478353; called by muse, mutect2, varscan2
- KCNH3 | c.2993C>G p.S998* | Nonsense Mutation (SNP) | VAF 49/134 reads (37%) | catalogued as COSV99235733; called by muse, mutect2, varscan2
- KIAA0408 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV64108884; called by muse, mutect2, varscan2
- KIF22 | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV99361462; called by muse, mutect2
- KIF22 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99361339, COSV99361467; called by muse, varscan2
- KIF22 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV99361468; called by muse, mutect2
- KLF3 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs777382745, COSV99789942; called by muse, mutect2, varscan2
- KLHL1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.951); catalogued as COSV64769087; called by muse, mutect2, varscan2
- KLK2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 110/301 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV100320049; called by muse, mutect2, varscan2
- KMT2D | c.7618C>T p.Q2540* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV99979938; called by muse, mutect2, varscan2
- KRT40 | c.759C>G p.D253E | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898902; called by muse, mutect2, varscan2
- KRT76 | c.740C>G p.S247* | Nonsense Mutation (SNP) | VAF 102/269 reads (38%) | catalogued as COSV100196498, COSV60121502; called by muse, mutect2, varscan2
- LAMA5 | c.10118G>A p.R3373Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs1472165176, COSV53367260; called by muse, mutect2, varscan2
- LGR6 | c.2869C>T p.Q957* (on ENST00000367278 / NM_001017403.1; = p.Q905* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV55153027, COSV99707814; called by muse, mutect2, varscan2
- LHCGR | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV54292367, COSV99684170; called by muse, mutect2
- LRRC37B | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV100496506; called by muse, mutect2, varscan2
- LRRC4B | c.1433G>C p.G478A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV100976032, COSV65350035; called by muse, mutect2, varscan2
- LRRC4C | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99537799, COSV99539587; called by muse, mutect2, varscan2
- LSM3 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 11/235 reads (5%) | catalogued as COSV99542604; called by muse, mutect2
- MAGEA10 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 69/98 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as rs866425773, COSV99726901; called by muse, mutect2, varscan2
- MAGEA10 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 79/121 reads (65%) | SIFT tolerated (0.45); PolyPhen benign (0.07); catalogued as COSV99726902; called by muse, mutect2, varscan2
- MAGEA10 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 74/115 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs771907807, COSV99726904; called by muse, mutect2, varscan2
- MANBA | c.1823C>T p.S608F (on ENST00000642252; = p.S562F on NM_005908.4) | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374407182, COSV56963168; called by muse, mutect2, varscan2
- MAP3K1 | c.2022C>G p.I674M | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV101267104; called by muse, mutect2, varscan2
- MAP3K11 | c.2530G>A p.E844K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as COSV100442364; called by muse, mutect2, varscan2
- MAP3K13 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 10/321 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs1221645538, COSV99407882; called by muse, mutect2
- MAP3K19 | c.1892C>G p.S631C | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV100209214; called by muse, mutect2
- MED13 | c.2793C>G p.I931M | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1279876714, COSV101181345; called by muse, mutect2, varscan2
- METTL21C | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV57433707, COSV99940138; called by muse, mutect2, varscan2
- MICAL3 | c.5527G>C p.E1843Q | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101490959; called by muse, mutect2, varscan2
- MRRF | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs565042307, COSV99939048; called by muse, mutect2, varscan2
- MTBP | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | catalogued as COSV100011950, COSV100012652, COSV59966168; called by muse, mutect2, varscan2
- MUC5B | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs753649259, COSV101500721; called by muse, mutect2, varscan2
- MUC5B | c.15306G>A p.M5102I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as rs754750652, COSV71594018; called by muse, mutect2, varscan2
- MXRA5 | c.7530G>C p.K2510N | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as rs372219810, COSV99479050; called by muse, varscan2
- MYO7B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371035844; called by muse, mutect2, varscan2
- MYO9A | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV100614241; called by muse, mutect2, varscan2
- MYO9B | c.5161G>C p.E1721Q | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV101261898; called by muse, mutect2, varscan2
- MYRF | c.2762C>T p.S921L (on ENST00000278836 / NM_001127392.3; = p.S886L on NM_013279.4) | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.077); catalogued as COSV53892660; called by muse, mutect2, varscan2
- NAP1L3 | c.1326C>G p.F442L | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100220640, COSV59073368, COSV59074349; called by muse, mutect2, varscan2
- NBR1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1447301315, COSV100357985; called by muse, mutect2, varscan2
- NCOA5 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV99275988; called by muse, mutect2
- NCOR2 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100657835; called by muse, mutect2, varscan2
- NCSTN | c.1575C>G p.F525L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99667591; called by muse, varscan2
- NDUFS5 | c.320G>C p.*107Sext*10 | Nonstop Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV100880481, COSV65892549; called by muse, mutect2, varscan2
- NECTIN3 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100162714; called by muse, mutect2, varscan2
- NELL1 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100124703; called by muse, mutect2, varscan2
- NKAPL | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100642574; called by muse, mutect2, varscan2
- NKX6-1 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99880185; called by muse, mutect2, varscan2
- NPRL3 | c.1040C>T p.P347L (on ENST00000611875 / NM_001077350.3; = p.P322L on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as rs755232774, COSV101302038; called by muse, mutect2, varscan2
- NRDC | c.3219G>C p.K1073N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV100544029; called by muse, mutect2, varscan2
- NRG3 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100930654, COSV100932530; called by muse, mutect2, varscan2
- NRP1 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs369312020, COSV55176822; called by muse, mutect2, varscan2
- NRP2 | c.2522C>T p.S841F (on ENST00000360409 / NM_201266.2; = p.S836F on NM_003872.3) | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV100761327; called by muse, mutect2, varscan2
- OIT3 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1228071794, COSV100467617; called by muse, mutect2
- OR2L13 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100813884; called by muse, mutect2
- OR56A3 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 121/287 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61569486; called by muse, mutect2, varscan2
- OR6B2 | c.489C>G p.I163M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as COSV99401730; called by muse, mutect2, varscan2
- PARP9 | c.2470G>C p.E824Q | Missense Mutation (SNP) | VAF 98/169 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100831253; called by muse, mutect2, varscan2
- PARP9 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs559272508, COSV64451765; called by muse, mutect2, varscan2
- PAX8 | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 7/110 reads (6%) | catalogued as COSV54507641; called by muse, mutect2
- PEX11G | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55537424, COSV99675917; called by muse, mutect2, varscan2
- PHF14 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.225); catalogued as COSV71002953; called by muse, mutect2, varscan2
- PHKG1 | c.993G>C p.E331D | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV51915757, COSV99305418; called by muse, mutect2, varscan2
- PIBF1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100411901; called by muse, mutect2, varscan2
- PIBF1 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.787); catalogued as COSV100411903; called by muse, mutect2, varscan2
- PIK3C2A | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 66/172 reads (38%) | catalogued as COSV99791164; called by muse, mutect2, varscan2
- PKD1 | c.4808C>T p.S1603F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99238985; called by muse, mutect2
- PLAG1 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV100388194; called by muse, mutect2, varscan2
- PLCE1 | c.4013G>T p.G1338V | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV99596967; called by muse, mutect2, varscan2
- PLCE1 | c.6397G>A p.E2133K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV99596971; called by muse, mutect2, varscan2
- PLXNB2 | c.3647C>A p.S1216Y | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.949); catalogued as COSV100834057, COSV100834278; called by muse, mutect2, varscan2
- POLR2C | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV54671720, COSV99538454; called by muse, mutect2, varscan2
- PPARG | c.651G>C p.E217D (on ENST00000287820 / NM_015869.5; = p.E187D on NM_005037.7) | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99826760; called by muse, mutect2, varscan2
- PPP1R12A | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99700798; called by mutect2, varscan2
- PRKACB | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100853998; called by muse, mutect2, varscan2
- PSPN | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99831795; called by muse, mutect2, varscan2
- RASGRF1 | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as COSV101174747; called by muse, mutect2, varscan2
- RBL2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100044028; called by muse, mutect2, varscan2
- RENBP | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV64170094; called by muse, mutect2, varscan2
- REV1 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767978619, COSV51490652; called by muse, mutect2, varscan2
- RIPPLY2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV100859545; called by muse, mutect2, varscan2
- RNASET2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 125/483 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs754474033, COSV99218661; called by muse, mutect2
- ROR2 | c.2437C>A p.P813T | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); catalogued as COSV100996094, COSV65223419; called by muse, mutect2, varscan2
- RUNDC1 | c.1496C>G p.S499C | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100865890; called by muse, mutect2, varscan2
- SAMD9L | c.4492G>A p.D1498N | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100561114; called by muse, mutect2, varscan2
- SBF2 | c.1259G>C p.R420T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99815613; called by muse, mutect2, varscan2
- SBNO1 | c.1898C>G p.S633C (on ENST00000420886; = p.S632C on NM_018183.5) | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99929626; called by muse, mutect2
- SBNO1 | c.1645C>T p.L549F (on ENST00000420886; = p.L548F on NM_018183.5) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV99929629; called by muse, mutect2
- SBNO1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as COSV99929631; called by muse, mutect2, varscan2
- SCN11A | c.3811G>C p.E1271Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100182430; called by muse, mutect2, varscan2
- SENP5 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV100052258; called by muse, mutect2, varscan2
- SERPINA9 | c.328A>C p.I110L | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); catalogued as COSV100098747; called by muse, mutect2, varscan2
- SH3GLB2 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100999379; called by muse, varscan2
- SHOC1 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100597992; called by muse, mutect2, varscan2
- SHOC1 | c.1382C>G p.A461G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as COSV100597994; called by muse, mutect2, varscan2
- SLC2A4 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV99142812; called by muse, mutect2, varscan2
- SLC35A5 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as COSV99656912; called by muse, mutect2, varscan2
- SMARCAL1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100620053; called by muse, mutect2, varscan2
- SNAPC3 | c.981-1G>C p.X327_splice | Splice Site (SNP) | VAF 36/75 reads (48%) | catalogued as COSV101070272; called by muse, mutect2, varscan2
- SPEG | c.4123G>A p.E1375K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV100405541; called by muse, mutect2, varscan2
- SRGAP1 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 25/50 reads (50%) | catalogued as COSV100755091; called by muse, mutect2, varscan2
- SRRM2 | c.4281G>A p.M1427I | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100071450; called by muse, mutect2
- SRRM2 | c.4343G>C p.R1448T | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV57068008; called by muse, mutect2
- ST18 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs764090853, COSV52488539, COSV99390930; called by muse, mutect2
- STON1 | c.217C>G p.P73A | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100562259; called by muse, mutect2
- STYXL2 | c.3306G>C p.E1102D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1047385536, COSV99609836; called by muse, mutect2, varscan2
- SUV39H1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV100551840, COSV61920333; called by muse, mutect2, varscan2
- SYNE2 | c.17980G>A p.D5994N | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV100648428; called by muse, mutect2, varscan2
- TACC2 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs778422472, COSV100553696; called by muse, mutect2, varscan2
- TAF3 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as rs748291820, COSV100720466, COSV60206492; called by muse, mutect2, varscan2
- TBX21 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99456305; called by muse, varscan2
- TEP1 | c.7870C>A p.L2624M | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777068772, COSV52997810; called by muse, varscan2
- TEX15 | c.3664A>C p.S1222R (on ENST00000256246; = p.S1605R on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV99822052; called by muse, mutect2, varscan2
- TGFBR2 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV55444001; called by muse, mutect2, varscan2
- TIAM2 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51639190, COSV99265969; called by muse, mutect2, varscan2
- TJP1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs375824999; called by muse, mutect2, varscan2
- TKT | c.1110G>A p.V370= | Splice Region (SNP) | VAF 13/17 reads (76%) | catalogued as COSV99965146; called by muse, mutect2, varscan2
- TLK2 | c.2174G>A p.R725Q (on ENST00000326270 / NM_001284333.2; = p.R703Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs769484053, COSV58299162; called by muse, mutect2, varscan2
- TLR4 | c.280G>A p.E94K (on ENST00000355622 / NM_138554.5; = p.E54K on NM_003266.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100790693, COSV62922466; called by muse, mutect2, varscan2
- TMCC1 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 88/175 reads (50%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.01); catalogued as COSV101282063; called by muse, mutect2, varscan2
- TMPRSS11F | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV100678797; called by muse, mutect2, varscan2
- TNN | c.3802C>G p.P1268A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53422148, COSV99512875; called by muse, mutect2
- TRMT2A | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as rs746476053, COSV52813778; called by muse, mutect2, varscan2
- TRRAP | c.8750G>A p.R2917H (on ENST00000359863 / NM_001244580.1; = p.R2899H on NM_003496.3) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1250625061, COSV100722894; called by muse, mutect2, varscan2
- TTN | c.76603C>T p.R25535C (on ENST00000591111; = p.R18111C on NM_003319.4) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | PolyPhen possibly damaging (0.804); catalogued as rs778385749, COSV100628112; called by muse, mutect2, varscan2
- TTN | c.59299G>C p.E19767Q (on ENST00000591111; = p.E12343Q on NM_003319.4) | Missense Mutation (SNP) | VAF 50/129 reads (39%) | PolyPhen possibly damaging (0.711); catalogued as COSV100628115; called by muse, varscan2
- TTN | c.59217G>C p.K19739N (on ENST00000591111; = p.K12315N on NM_003319.4) | Missense Mutation (SNP) | VAF 45/160 reads (28%) | PolyPhen probably damaging (0.997); catalogued as COSV100628117; called by muse, varscan2
- UBA1 | c.2194G>C p.D732H | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV100256055; called by muse, mutect2, varscan2
- UBAP2 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100671904; called by muse, mutect2, varscan2
- UPF2 | c.1655-1G>A p.X552_splice | Splice Site (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100707437; called by muse, varscan2
- USP33 | c.2695G>C p.E899Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV100657227, COSV100657252; called by muse, mutect2
- USP34 | c.447G>C p.W149C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101277196; called by muse, varscan2
- USP34 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as COSV101277197, COSV68402748; called by muse, varscan2
- USP9X | c.7306C>T p.Q2436* | Nonsense Mutation (SNP) | VAF 42/59 reads (71%) | catalogued as COSV61073655; called by muse, mutect2, varscan2
- UTP20 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99882473; called by muse, mutect2, varscan2
- UTS2B | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs200863229; called by muse, mutect2, varscan2
- VARS2 | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs1418135349, COSV100423063; called by muse, mutect2, varscan2
- VAV2 | c.1852G>C p.E618Q (on ENST00000371850 / NM_001134398.2; = p.E608Q on NM_003371.4) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV100896158; called by muse, mutect2, varscan2
- VRTN | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99832476; called by muse, mutect2, varscan2
- WASHC2A | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99254777; called by muse, mutect2, varscan2
- WDR59 | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV100049700; called by muse, mutect2
- WIPF2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100063893; called by muse, mutect2, varscan2
- WWC2 | c.3357G>C p.Q1119H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV101331082; called by muse, mutect2, varscan2
- ZC3H15 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.677); catalogued as COSV100552205; called by muse, mutect2, varscan2
- ZCCHC9 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs148607166, COSV99562718; called by muse, mutect2, varscan2
- ZFYVE16 | c.2645T>C p.V882A | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV100566628; called by muse, mutect2, varscan2
- ZIM3 | c.1379C>A p.S460* | Nonsense Mutation (SNP) | VAF 43/116 reads (37%) | catalogued as COSV99518600; called by muse, mutect2, varscan2
- ZNF10 | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs768134483, COSV50216303; called by muse, mutect2, varscan2
- ZNF112 | c.1162G>A p.E388K (on ENST00000337401 / NM_001083335.2; = p.E382K on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100496232; called by muse, mutect2, varscan2
- ZNF112 | c.931G>T p.D311Y (on ENST00000337401 / NM_001083335.2; = p.D305Y on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as COSV100496236; called by muse, mutect2, varscan2
- ZNF182 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.459); catalogued as COSV100527194; called by muse, mutect2, varscan2
- ZNF197 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100482240; called by muse, mutect2, varscan2
- ZNF23 | c.200C>G p.S67* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as rs1176420550, COSV100612263; called by muse, mutect2, varscan2
- ZNF300 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.04); catalogued as COSV99200104; called by muse, varscan2
- ZNF462 | c.5830G>C p.D1944H | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99473183; called by muse, mutect2
- ZNF470 | c.1416G>C p.Q472H | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100401286, COSV100401388; called by muse, mutect2
- ZNF562 | c.997C>G p.Q333E (on ENST00000453372 / NM_001130032.2; = p.Q261E on NM_017656.4) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs900591787, COSV99530860; called by muse, mutect2, varscan2
- ZNF592 | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100246110; called by muse, mutect2, varscan2
- ZNF668 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100336866; called by muse, mutect2, varscan2
- ZNF721 | c.1447C>A p.H483N (on ENST00000338977; = p.H495N on NM_133474.4) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100167777; called by muse, mutect2, varscan2
- ZNF750 | c.632C>G p.S211* | Nonsense Mutation (SNP) | VAF 78/102 reads (76%) | catalogued as COSV99489935; called by muse, mutect2, varscan2
- AJUBA | c.1519del p.E507Kfs*54 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- IGHV3-38 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 129/319 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MAGEB6B | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 70/114 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- MYO10 | c.5479_5488del p.Q1828Lfs*55 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- TMC5 | c.604_605del p.L202Gfs*4 | Frame Shift Del (DEL) | VAF 52/196 reads (27%) | called by pindel, varscan2
- UPF2 | c.1669del p.E557Kfs*11 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | called by pindel, varscan2
- ABCA7 | c.861G>A p.L287= | Silent (SNP) | VAF 57/169 reads (34%) | catalogued as COSV54037651; called by muse, mutect2, varscan2
- ABCC5 | c.2055G>A p.L685= | Silent (SNP) | VAF 92/174 reads (53%) | catalogued as COSV99656713, COSV99657523; called by muse, mutect2, varscan2
- ABTB2 | c.2859G>A p.V953= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as COSV100132090; called by muse, mutect2
- ACP7 | c.945C>T p.Y315= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs548565452, COSV58698583; called by muse, mutect2, varscan2
- ACTL7A | c.84C>G p.L28= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100453206; called by muse, mutect2
- ADAMTSL4 | c.1506G>A p.K502= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV99647876; called by muse, mutect2
- ADGRL1 | c.405G>A p.Q135= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100529414, COSV100529791; called by muse, mutect2, varscan2
- ALDH1L2 | c.2523C>T p.I841= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as rs143634333; called by muse, mutect2, varscan2
- ANKRD1 | c.657C>G p.L219= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100865362; called by muse, mutect2, varscan2
- AP3B1 | c.3165G>A p.L1055= | Silent (SNP) | VAF 43/68 reads (63%) | catalogued as COSV54887720; called by muse, mutect2, varscan2
- AP3D1 | c.3045G>A p.Q1015= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs1471204444, COSV100642369; called by muse, mutect2, varscan2
- ARHGAP39 | c.2604G>A p.K868= (on ENST00000276826 / NM_001308208.2; = p.K899= on NM_025251.2) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs1195440431, COSV99432181, COSV99432192; called by muse, mutect2, varscan2
- ARHGEF19 | c.1218C>T p.A406= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99580739; called by muse, mutect2, varscan2
- BAG6 | c.1269G>A p.P423= | Silent (SNP) | VAF 74/188 reads (39%) | catalogued as rs572580953, COSV99277565; called by muse, mutect2, varscan2
- BCL11A | c.1344C>T p.N448= (on ENST00000335712 / NM_001365609.1; = p.N482= on NM_018014.4) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100186426; called by muse, mutect2, varscan2
- BRWD3 | c.3660C>T p.F1220= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV100956490; called by muse, mutect2, varscan2
- C1QTNF9B | c.843G>A p.V281= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV101158630; called by muse, mutect2, varscan2
- CABP7 | c.585C>T p.I195= | Silent (SNP) | VAF 108/213 reads (51%) | catalogued as rs746286699, COSV53362431; called by muse, mutect2, varscan2
- CAMSAP1 | c.3714C>T p.L1238= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs776722982, COSV100410414; called by muse, mutect2, varscan2
- CAMTA1 | c.3487C>T p.L1163= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as COSV100352258; called by muse, mutect2, varscan2
- CCDC22 | c.1002C>G p.L334= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as COSV100873154, COSV100873254; called by muse, varscan2
- CCL8 | c.144G>A p.L48= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV101126440; called by muse, mutect2
- CEACAM6 | c.975C>T p.L325= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV99555722; called by muse, mutect2
- CEP63 | c.846C>G p.L282= | Silent (SNP) | VAF 78/136 reads (57%) | catalogued as COSV100133080; called by muse, mutect2, varscan2
- CFAP61 | c.2595C>T p.L865= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV55633541; called by muse, mutect2, varscan2
- CNR2 | c.430C>T p.L144= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV100991585; called by muse, mutect2
- CTSF | c.1260C>T p.L420= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100074486; called by muse, mutect2, varscan2
- CYP1B1 | c.342C>T p.F114= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs753937479, COSV99572828; called by muse, mutect2, varscan2
- CYP4F12 | c.1329C>T p.F443= | Silent (SNP) | VAF 87/249 reads (35%) | catalogued as COSV100216130; called by muse, mutect2
- DDX42 | c.1929C>T p.F643= | Silent (SNP) | VAF 61/193 reads (32%) | catalogued as COSV100835057; called by muse, mutect2, varscan2
- EML3 | c.1743G>C p.L581= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as COSV99604502; called by muse, mutect2, varscan2
- FAM217A | c.189G>A p.L63= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99212800; called by muse, mutect2, varscan2
- FAT2 | c.7704C>T p.F2568= | Silent (SNP) | VAF 93/161 reads (58%) | catalogued as COSV99944029; called by muse, mutect2, varscan2
- FCER1G | c.237G>A p.L79= | Silent (SNP) | VAF 60/148 reads (41%) | catalogued as COSV99248444; called by muse, mutect2, varscan2
- FIGN | c.1521G>A p.L507= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100292939; called by muse, mutect2
- FRAS1 | c.5601G>A p.Q1867= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99355543; called by muse, mutect2, varscan2
- GGH | c.57G>A p.A19= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs1373327650, COSV99479023; called by muse, mutect2, varscan2
- GJB4 | c.558C>T p.F186= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV58356904; called by muse, mutect2, varscan2
- GLI1 | c.2499C>G p.L833= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV99954657; called by muse, mutect2
- GPAT2 | c.1608C>T p.L536= | Silent (SNP) | VAF 54/154 reads (35%) | catalogued as COSV100853350; called by muse, mutect2, varscan2
- GRHPR | c.525C>T p.F175= | Silent (SNP) | VAF 63/188 reads (34%) | catalogued as rs749885934, COSV58945798; called by muse, mutect2, varscan2
- H2AC8 | c.392G>A p.*131= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs1449000650, COSV99773376; called by muse, varscan2
- HEATR5B | c.1720C>T p.L574= | Silent (SNP) | VAF 68/135 reads (50%) | catalogued as COSV99250153; called by muse, mutect2, varscan2
- HIVEP1 | c.2508C>T p.I836= | Silent (SNP) | VAF 58/153 reads (38%) | catalogued as COSV101045686; called by muse, mutect2, varscan2
- HNRNPDL | c.255C>A p.L85= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV55022592, COSV99787058, COSV99787212; called by muse, mutect2, varscan2
- HSDL2 | c.963C>G p.L321= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV99357117; called by muse, mutect2, varscan2
- HTR1B | c.1008G>A p.V336= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as rs1432615429, COSV100885475; called by muse, mutect2, varscan2
- HVCN1 | c.372G>C p.L124= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV99657437; called by muse, mutect2, varscan2
- HVCN1 | c.120C>T p.I40= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99657443; called by muse, mutect2, varscan2
- IGFBP5 | c.510G>A p.E170= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV52083033; called by muse, mutect2, varscan2
- INF2 | c.954C>G p.L318= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1324424829, COSV99384296; called by muse, mutect2, varscan2
- IPO4 | c.3240C>T p.L1080= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100269041, COSV100269223; called by muse, mutect2, varscan2
- IRX1 | c.426C>G p.L142= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs763588883, COSV100116764; called by muse, mutect2, varscan2
- IRX5 | c.135C>T p.F45= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100315981; called by muse, mutect2, varscan2
- KIAA0319 | c.1797G>A p.L599= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100985786; called by muse, mutect2, varscan2
- KIF21B | c.4770C>T p.I1590= (on ENST00000422435 / NM_001252100.2; = p.I1577= on NM_017596.4) | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as COSV100145073; called by muse, mutect2, varscan2
- KIF22 | c.357G>A p.Q119= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs1300084174, COSV99361465; called by muse, mutect2
- LY75-CD302 | c.5043C>G p.L1681= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99374637; called by muse, mutect2, varscan2
- MAP4K1 | c.222C>T p.I74= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs771465583, COSV50264269; called by muse, varscan2
- MPP3 | c.561C>T p.N187= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs767969540, COSV101263364; called by muse, mutect2, varscan2
- MUC5AC | c.1605C>T p.I535= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV62253853; called by muse, mutect2
- MXRA5 | c.7704G>A p.G2568= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as rs1339159730, COSV99479046; called by muse, mutect2, varscan2
- MYH13 | c.1074G>C p.V358= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV52836180, COSV99355345; called by muse, mutect2
- MYO15A | c.8868C>T p.F2956= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99234305; called by muse, mutect2, varscan2
- MYOM2 | c.2748C>T p.I916= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV50801733; called by muse, mutect2, varscan2
- NLRP12 | c.1281G>A p.T427= | Silent (SNP) | VAF 112/258 reads (43%) | catalogued as rs528087095, COSV60749018; called by muse, mutect2, varscan2
- NPAS2 | c.2202G>A p.Q734= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs772318572, COSV100176901; called by muse, varscan2
- NUP160 | c.3387C>A p.L1129= | Silent (SNP) | VAF 76/188 reads (40%) | catalogued as COSV101021622; called by muse, mutect2, varscan2
- OIT3 | c.927C>G p.L309= | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as COSV100468331; called by muse, mutect2
- OR10G7 | c.768C>T p.F256= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs867513894, COSV57865846; called by muse, mutect2, varscan2
- OR51T1 | c.384C>T p.I128= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV100434481; called by muse, mutect2
- PACSIN3 | c.1146G>T p.L382= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV100096581; called by muse, mutect2, varscan2
- PCDH11X | c.834A>T p.I278= | Silent (SNP) | VAF 44/76 reads (58%) | catalogued as COSV100014845; called by muse, varscan2
- PCDHB15 | c.1623G>A p.L541= | Silent (SNP) | VAF 64/101 reads (63%) | catalogued as COSV51331653, COSV99179165; called by muse, mutect2, varscan2
- PLEC | c.11622G>T p.V3874= (on ENST00000322810 / NM_201380.4; = p.V3764= on NM_000445.5) | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV100518540; called by muse, mutect2, varscan2
- PM20D1 | c.1263G>A p.P421= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs775577746, COSV65649074; called by muse, mutect2, varscan2
- PPM1J | c.1517G>A p.*506= | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- PPP1CC | c.318C>T p.L106= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100534960; called by muse, varscan2
- PTGFRN | c.2298C>T p.L766= | Silent (SNP) | VAF 71/189 reads (38%) | catalogued as COSV101277456; called by muse, mutect2, varscan2
- PTGS1 | c.1605G>A p.G535= | Silent (SNP) | VAF 67/194 reads (35%) | catalogued as rs542367354, COSV99793516; called by muse, mutect2, varscan2
- RECQL5 | c.237C>G p.L79= | Silent (SNP) | VAF 255/322 reads (79%) | catalogued as COSV99503032; called by muse, varscan2
- RGL2 | c.849C>G p.L283= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV101004835; called by muse, mutect2, varscan2
- RNASEL | c.324G>A p.L108= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100842641; called by muse, mutect2, varscan2
- SACS | c.1731C>T p.F577= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as COSV101207704; called by muse, mutect2, varscan2
- SBDS | c.579G>A p.L193= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1488948286, COSV99886196; called by muse, mutect2, varscan2
- SERPINB3 | c.12C>G p.L4= | Silent (SNP) | VAF 85/240 reads (35%) | catalogued as COSV99380184; called by muse, mutect2, varscan2
- SLC26A7 | c.669C>A p.I223= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99404252; called by muse, mutect2, varscan2
- SMPD3 | c.462C>T p.I154= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs369737564; called by muse, mutect2, varscan2
- SNX29 | c.174G>A p.K58= | Silent (SNP) | VAF 101/262 reads (39%) | catalogued as COSV101625459; called by muse, mutect2, varscan2
- STK24 | c.630G>A p.S210= | Silent (SNP) | VAF 69/211 reads (33%) | catalogued as rs749488403, COSV100924934, COSV100925012, COSV100925013; called by muse, mutect2, varscan2
- STX12 | c.495G>A p.Q165= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100881377; called by muse, mutect2, varscan2
- STX2 | c.582C>T p.I194= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs190226290, COSV55431957; called by muse, mutect2, varscan2
- SYT1 | c.939G>A p.V313= | Silent (SNP) | VAF 4/77 reads (5%) | catalogued as rs1423758690, COSV99697272; called by muse, mutect2
- TMEM268 | c.720G>T p.V240= | Silent (SNP) | VAF 59/155 reads (38%) | catalogued as COSV99938812; called by muse, mutect2, varscan2
- TMEM39A | c.225T>C p.F75= | Silent (SNP) | VAF 43/214 reads (20%) | catalogued as COSV100052630; called by muse, mutect2, varscan2
- TMOD1 | c.660G>A p.L220= | Silent (SNP) | VAF 17/231 reads (7%) | catalogued as COSV99404065, COSV99404170; called by muse, mutect2
- TNXB | c.10050G>A p.A3350= (on ENST00000647633; = p.A3103= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as rs762962693, COSV100926608; called by muse, mutect2, varscan2
- TOR1AIP1 | c.240G>A p.P80= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV99621634; called by muse, mutect2, varscan2
- TRMU | c.574C>T p.L192= | Silent (SNP) | VAF 102/209 reads (49%) | catalogued as rs149815191, COSV99324694; called by muse, mutect2, varscan2
- UPF2 | c.1749G>C p.L583= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100707435; called by muse, varscan2
- VEPH1 | c.828G>A p.L276= | Silent (SNP) | VAF 129/204 reads (63%) | catalogued as COSV100747999; called by muse, mutect2, varscan2
- WIPF2 | c.141G>A p.G47= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV100063894; called by muse, mutect2, varscan2
- WNT2 | c.57C>T p.L19= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as rs781420620, COSV55410390; called by muse, mutect2, varscan2
- WSCD1 | c.288G>A p.R96= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1490068360, COSV100496797; called by muse, mutect2
- ZNF300 | c.336G>A p.L112= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99200112; called by muse, varscan2
- ZNF606 | c.594C>T p.V198= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as COSV100357520; called by muse, mutect2
- ZSCAN16 | c.903C>T p.F301= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs1278049727, COSV100481536; called by muse, mutect2, varscan2
- ZSCAN22 | c.1269G>A p.L423= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV100308486; called by muse, mutect2, varscan2
- ADAM8 | c.*89C>G | 3'UTR (SNP) | VAF 40/160 reads (25%) | catalogued as COSV101291739; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845643 G>A | 5'Flank (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- ANKRD33 | c.-334G>A | 5'UTR (SNP) | VAF 60/176 reads (34%) | catalogued as COSV100001506; called by muse, mutect2, varscan2
- CTDSP2 | c.412-354T>C | Intron (SNP) | VAF 3/41 reads (7%) | catalogued as COSV101143084; called by muse, mutect2
- DCHS2 | n.4669G>C | RNA (SNP) | VAF 41/139 reads (29%) | catalogued as COSV100602571; called by muse, mutect2, varscan2
- DCHS2 | n.3951G>C | RNA (SNP) | VAF 11/33 reads (33%) | catalogued as rs759769096, COSV100601557, COSV61767998, COSV61774246; called by muse, mutect2, varscan2
- GRK5 | c.148+7175G>C | Intron (SNP) | VAF 15/46 reads (33%) | catalogued as rs747929071; called by muse, mutect2, varscan2
- OR4K1 | c.*2G>A | 3'UTR (SNP) | VAF 11/58 reads (19%) | catalogued as rs1432806444, COSV53458982; called by muse, mutect2, varscan2
- SSPOP | n.3542C>T | RNA (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100022944, COSV50486270; called by muse, mutect2, varscan2
- SSPOP | n.15678G>A | RNA (SNP) | VAF 32/90 reads (36%) | catalogued as COSV65130174; called by muse, mutect2, varscan2
- STAG3L2 | n.442G>T | RNA (SNP) | VAF 155/555 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.10360+3178G>A | Intron (SNP) | VAF 18/55 reads (33%) | catalogued as rs867360963, COSV100628120; called by muse, mutect2, varscan2
- TTN | c.10360+2434G>T | Intron (SNP) | VAF 15/39 reads (38%) | catalogued as rs758950243, COSV100626678, COSV100628123; called by muse, mutect2, varscan2
- TTN | c.10360+1987G>A | Intron (SNP) | VAF 25/58 reads (43%) | catalogued as rs868633339, COSV100605532; called by muse, mutect2, varscan2
